Somatic mutation profile of tumor specimen TARGET-15-SJMPAL011912-09A.1 (aliquot TARGET-15-SJMPAL011912-09A.1-01D) from TARGET case TARGET-15-SJMPAL011912, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.0 years (4,386 days).
Specimen TARGET-15-SJMPAL011912-09A.1: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e98f3a1-66c8-4bd0-8132-b74466d5ddfe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL011912-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL011912-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8fcb8b3e-d06f-4ad6-8fb6-593d13472aab

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 2, Frame Shift Ins 2, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD18B | c.2293G>A p.E765K | Missense Mutation (SNP) | VAF 29/268 reads (11%) | SIFT tolerated (0.97); PolyPhen benign (0.015); catalogued as rs772929260; called by muse, mutect2, varscan2
- BLID | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 67/133 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.9); catalogued as rs1431967565; called by muse, mutect2, varscan2
- DDX3X | c.1756C>A p.R586S (on ENST00000399959; = p.R587S on NM_001356.5) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.969); catalogued as COSV101302422; called by muse, mutect2
- MUC5B | c.6430G>A p.G2144S | Missense Mutation (SNP) | VAF 127/285 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.018); catalogued as rs774697644; called by muse, mutect2, varscan2
- TBC1D32 | c.3661G>T p.A1221S | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.065); catalogued as COSV99251103; called by muse, mutect2
- TJP3 | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.034); catalogued as rs774239353; called by muse, varscan2
- TPH2 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs1462726765, COSV61590829, COSV61591310, COSV61591702; called by muse, mutect2
- WT1 | c.1264_1265insTAAA p.R422Lfs*22 | Frame Shift Ins (INS) | VAF 118/246 reads (48%) | catalogued as COSV60070980, COSV60080799, COSV60083260; called by mutect2, pindel, varscan2
- WT1 | c.1069_1070insA p.R357Qfs*16 | Frame Shift Ins (INS) | VAF 40/108 reads (37%) | catalogued as COSV60066697, COSV60067983, COSV60072980, COSV60075200, COSV60076698, COSV60085048, COSV99070062; called by mutect2, pindel*, varscan2
- GJA5 | c.715G>T p.V239F | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.035); called by muse, mutect2
- NDUFAF3 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- NEIL3 | c.881C>A p.T294N | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.011); called by muse, varscan2
- TULP1 | c.829-1G>T p.X277_splice | Splice Site (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- VIL1 | c.1649C>A p.T550N | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- AQP12B | c.216G>A p.G72= (on ENST00000621682; = p.G84= on NM_001102467.2) | Silent (SNP) | VAF 29/87 reads (33%) | called by muse, mutect2, varscan2
- PCDHGA7 | c.810C>T p.D270= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as COSV53912854, COSV53988586; called by muse, mutect2, varscan2
- RNF151 | c.-7G>C | 5'UTR (SNP) | VAF 6/14 reads (43%) | called by muse, varscan2
